Somatic mutation profile of tumor specimen SM-JU32S (aliquot 7316UP-1883) from CPTAC case C685110, project CPTAC-3 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Intraductal carcinoma, NOS; Tissue or organ of origin: Breast, NOS.
Specimen SM-JU32S: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Cerebrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ad0172f-d3c4-4fd7-8dbf-e03903d43410.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105277 (Blood Derived Normal), aliquot 7316UP-1640-1105277; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f63b87b1-90f0-4361-b49f-bf5dfe2665fd

The open-access MAF lists 162 somatic variants for this specimen: 119 protein-altering or splice-affecting, 22 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 22, Frame Shift Del 18, Intron 9, Splice Site 8, Nonsense Mutation 8, 5'UTR 7, In Frame Del 5, Splice Region 5, Frame Shift Ins 3, 3'Flank 2, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAP1 | c.1358_1359del p.K453Rfs*15 | Frame Shift Del (DEL) | VAF 79/231 reads (34%) | catalogued as rs1351986946; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCA10 | c.2313del p.R772Efs*8 | Frame Shift Del (DEL) | VAF 137/382 reads (36%) | catalogued as COSV52226795; called by mutect2, pindel, varscan2
- AMBRA1 | c.2058_2060del p.E686del (on ENST00000458649 / NM_001367468.1; = p.E596del on NM_017749.3 and 3 other RefSeq transcripts) | In Frame Del (DEL) | VAF 36/347 reads (10%) | catalogued as rs1565271272; called by pindel, varscan2
- ANXA13 | c.610C>T p.Q204* | Nonsense Mutation (SNP) | VAF 59/170 reads (35%) | catalogued as COSV51625648; called by muse, mutect2, varscan2
- CHPT1 | c.477G>T p.W159C | Missense Mutation (SNP) | VAF 27/179 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs755474481, COSV57533212; called by muse, mutect2, varscan2
- CSTF2T | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 39/262 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.767); catalogued as rs573214790; called by muse, mutect2, varscan2
- EHD2 | c.535G>T p.A179S | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV54407896, COSV99621506; called by muse, mutect2
- EXOC3L2 | c.1517G>A p.R506Q | Missense Mutation (SNP) | VAF 64/272 reads (24%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.546); catalogued as rs146408436, COSV99374660; called by muse, mutect2, varscan2
- FTHL17 | c.514G>T p.D172Y | Missense Mutation (SNP) | VAF 56/196 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV63266312; called by muse, varscan2
- GMDS | c.1005C>G p.D335E | Missense Mutation (SNP) | VAF 94/251 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.305); catalogued as COSV101070491; called by muse, mutect2, varscan2
- HOXA10 | c.946_948del p.K316del | In Frame Del (DEL) | VAF 425/989 reads (43%) | catalogued as rs1264111265; called by mutect2, pindel, varscan2
- IFT172 | c.5093T>C p.I1698T | Missense Mutation (SNP) | VAF 78/220 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as rs762114339, COSV99274945; called by muse, mutect2, varscan2
- ITGAV | c.2706+7G>A | Splice Region (SNP) | VAF 198/300 reads (66%) | catalogued as rs776851066, COSV53719519; called by muse, mutect2, varscan2
- LRRC6 | c.130C>T p.R44W | Missense Mutation (SNP) | VAF 82/238 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs189293241, COSV51538239; called by muse, mutect2, varscan2
- MAP4K1 | c.2341-7del | Splice Region (DEL) | VAF 40/144 reads (28%) | catalogued as rs767461672, COSV101204269; called by mutect2, pindel, varscan2
- MLH3 | c.3593A>G p.K1198R | Missense Mutation (SNP) | VAF 97/541 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53157053; called by muse, mutect2, varscan2
- MRPS18B | c.358G>A p.V120M | Missense Mutation (SNP) | VAF 103/296 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs116524936; called by muse, mutect2, varscan2
- MSLNL | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 134/303 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs766186362; called by muse, mutect2, varscan2
- ODF2 | c.1622G>A p.G541E (on ENST00000434106 / NM_153433.2; = p.G517E on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV100654954; called by muse, mutect2, varscan2
- PRDM16 | c.2851T>A p.Y951N | Missense Mutation (SNP) | VAF 70/122 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99578259; called by muse, mutect2, varscan2
- PRSS53 | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs778137757, COSV99762745; called by muse, mutect2, varscan2
- RAD54L2 | c.1812C>G p.S604R | Missense Mutation (SNP) | VAF 85/153 reads (56%) | SIFT tolerated (0.05); PolyPhen benign (0.251); catalogued as COSV56582303; called by muse, mutect2, varscan2
- RANBP3 | c.1473G>A p.S491= (on ENST00000340578 / NM_007322.3; = p.S486= on NM_003624.3) | Splice Region (SNP) | VAF 50/182 reads (27%) | catalogued as rs1012413726, COSV50382238; called by muse, mutect2, varscan2
- RASAL3 | c.2972C>A p.T991K | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.535); catalogued as COSV54604678; called by muse, mutect2, varscan2
- RASEF | c.1029-1G>A p.X343_splice | Splice Site (SNP) | VAF 411/628 reads (65%) | catalogued as rs1444601094, COSV100907060; called by muse, mutect2, varscan2
- SCN5A | c.2718C>A p.C906* | Nonsense Mutation (SNP) | VAF 80/336 reads (24%) | catalogued as rs751681601; called by muse, mutect2, varscan2
- SUGP1 | c.1822C>T p.R608W | Missense Mutation (SNP) | VAF 151/453 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as rs747643478, COSV55920060, COSV99895724; called by muse, mutect2, varscan2
- SULT1A1 | c.854C>A p.A285E | Missense Mutation (SNP) | VAF 118/506 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as rs746968899; called by muse, mutect2, varscan2
- TNR | c.3593G>A p.R1198H | Missense Mutation (SNP) | VAF 132/208 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs368661657, COSV54873347; called by muse, mutect2, varscan2
- TP53 | c.944_945insCC p.P316Lfs*30 | Frame Shift Ins (INS) | VAF 96/195 reads (49%) | catalogued as COSV53220710; called by mutect2, pindel, varscan2
- TPD52L3 | c.347C>A p.A116D | Missense Mutation (SNP) | VAF 57/230 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.899); catalogued as rs1272991489; called by muse, mutect2, varscan2
- TUSC2 | c.79G>A p.G27R | Missense Mutation (SNP) | VAF 65/105 reads (62%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as rs1553717633; called by muse, mutect2, varscan2
- ZNF292 | c.7081C>T p.R2361C | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs376564177; called by muse, mutect2, varscan2
- ADAMTS18 | c.1841_1842del p.R614Tfs*4 | Frame Shift Del (DEL) | VAF 140/566 reads (25%) | called by pindel, varscan2
- ADAP1 | c.106C>G p.L36V | Missense Mutation (SNP) | VAF 406/500 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- AGO2 | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 81/226 reads (36%) | called by muse, mutect2, varscan2
- ANGPT2 | c.1032+2_1032+35del p.X344_splice | Splice Site (DEL) | VAF 39/77 reads (51%) | called by mutect2, pindel
- ANKRD36 | c.2887-1G>T p.X963_splice | Splice Site (SNP) | VAF 88/575 reads (15%) | called by muse, mutect2, varscan2
- ARHGAP35 | c.1731del p.F578Lfs*50 | Frame Shift Del (DEL) | VAF 68/196 reads (35%) | called by mutect2, pindel, varscan2
- ASB2 | c.1114G>T p.V372F | Missense Mutation (SNP) | VAF 258/354 reads (73%) | SIFT tolerated (0.72); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ATPAF1 | c.589-3_589-2del p.X197_splice (on ENST00000574428; = p.X220_splice on NM_022745.4) | Splice Site (DEL) | VAF 50/188 reads (27%) | called by pindel, varscan2
- BIRC2 | c.502G>C p.D168H | Missense Mutation (SNP) | VAF 49/194 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- C2orf73 | c.343_368del p.L115Kfs*33 | Frame Shift Del (DEL) | VAF 38/192 reads (20%) | called by mutect2, pindel
- COL4A3 | c.1234G>T p.D412Y | Missense Mutation (SNP) | VAF 165/292 reads (57%) | SIFT tolerated (0.81); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- COL9A1 | c.1835C>A p.P612Q | Missense Mutation (SNP) | VAF 302/825 reads (37%) | SIFT tolerated (0.79); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CSF3R | c.944C>G p.P315R | Missense Mutation (SNP) | VAF 208/364 reads (57%) | SIFT tolerated (0.29); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- DAZAP1 | c.218A>G p.H73R | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DENND4B | c.1097C>G p.P366R | Missense Mutation (SNP) | VAF 61/417 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- DHX9 | c.3346A>C p.K1116Q | Missense Mutation (SNP) | VAF 100/468 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DLC1 | c.3992G>T p.G1331V (on ENST00000276297 / NM_001348081.2; = p.G894V on NM_006094.5) | Missense Mutation (SNP) | VAF 80/157 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DMD | c.9500A>G p.N3167S | Missense Mutation (SNP) | VAF 223/659 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- DNAH17 | c.4681G>A p.A1561T | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- EAPP | c.402_411del p.D135Cfs*42 | Frame Shift Del (DEL) | VAF 42/247 reads (17%) | called by mutect2, pindel, varscan2
- EGR2 | c.68A>G p.D23G | Missense Mutation (SNP) | VAF 71/523 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- ENPEP | c.773A>T p.N258I | Missense Mutation (SNP) | VAF 61/160 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERN1 | c.1396C>T p.L466= | Splice Region (SNP) | VAF 57/606 reads (9%) | called by muse, mutect2
- ERRFI1 | c.488_491del p.S163Wfs*11 | Frame Shift Del (DEL) | VAF 158/336 reads (47%) | called by mutect2, pindel, varscan2
- ETAA1 | c.1011_1014del p.N337Kfs*10 | Frame Shift Del (DEL) | VAF 22/212 reads (10%) | called by mutect2, pindel
- EVI2B | c.790A>G p.T264A | Missense Mutation (SNP) | VAF 78/206 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- FAM181B | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.013); called by muse, mutect2
- FER1L5 | c.5383_5385del p.K1795del (on ENST00000623019; = p.K1759del on NM_001293083.2) | In Frame Del (DEL) | VAF 78/232 reads (34%) | called by mutect2, pindel, varscan2
- GART | c.812-4G>C | Splice Region (SNP) | VAF 36/116 reads (31%) | called by mutect2, varscan2
- GAS6 | c.900G>T p.M300I | Missense Mutation (SNP) | VAF 270/385 reads (70%) | SIFT tolerated (0.07); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- GBA | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 62/265 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- GLIPR1L2 | c.481-1G>C p.X161_splice | Splice Site (SNP) | VAF 62/130 reads (48%) | called by muse, mutect2, varscan2
- GPAA1 | c.1088C>T p.P363L | Missense Mutation (SNP) | VAF 146/618 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- GRIA2 | c.19A>G p.I7V | Missense Mutation (SNP) | VAF 56/105 reads (53%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GRIK4 | c.190G>T p.V64F | Missense Mutation (SNP) | VAF 227/318 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- JPH2 | c.250G>A p.G84S | Missense Mutation (SNP) | VAF 31/192 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KDF1 | c.1135T>C p.S379P | Missense Mutation (SNP) | VAF 115/211 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- LARP4B | c.1368A>T p.Q456H | Missense Mutation (SNP) | VAF 90/587 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- LRRC45 | c.856C>T p.Q286* | Nonsense Mutation (SNP) | VAF 110/468 reads (24%) | called by muse, mutect2, varscan2
- MBD5 | c.2419_2432del p.L807Tfs*19 | Frame Shift Del (DEL) | VAF 31/78 reads (40%) | called by mutect2, pindel, varscan2
- MS4A12 | c.620T>C p.M207T | Missense Mutation (SNP) | VAF 121/346 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC22 | c.2770G>A p.E924K | Missense Mutation (SNP) | VAF 136/362 reads (38%) | SIFT tolerated (0.25); called by muse, mutect2, varscan2
- MXRA5 | c.1944C>A p.Y648* | Nonsense Mutation (SNP) | VAF 38/102 reads (37%) | called by muse, mutect2, varscan2
- NCAN | c.3300_3319del p.Y1100* | Frame Shift Del (DEL) | VAF 97/477 reads (20%) | called by mutect2, pindel, varscan2
- NECTIN2 | c.1316A>T p.Y439F | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- NFKBIE | c.484_485del p.L162Afs*47 (on ENST00000275015; = p.L23Afs*47 on NM_004556.3) | Frame Shift Del (DEL) | VAF 203/733 reads (28%) | called by pindel, varscan2
- NUP153 | c.2272C>A p.L758I | Missense Mutation (SNP) | VAF 44/278 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR5I1 | c.425T>C p.I142T | Missense Mutation (SNP) | VAF 61/263 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR8G2P | c.836C>A p.T279N | Missense Mutation (SNP) | VAF 68/248 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- PDE5A | c.2058dup p.D687* | Frame Shift Ins (INS) | VAF 39/167 reads (23%) | called by pindel, varscan2
- PEG3 | c.2177G>T p.G726V | Missense Mutation (SNP) | VAF 65/179 reads (36%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- PGRMC2 | c.81T>A p.S27R | Missense Mutation (SNP) | VAF 123/351 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- PHLDA1 | c.821_856del p.A274_R286delinsG | In Frame Del (DEL) | VAF 87/153 reads (57%) | called by mutect2, pindel
- PI4K2A | c.229G>T p.V77L | Missense Mutation (SNP) | VAF 130/228 reads (57%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PIK3R1 | c.1132_1172del p.N378Lfs*3 (on ENST00000521381 / NM_181523.3; = p.N108Lfs*3 on NM_181504.4) | Frame Shift Del (DEL) | VAF 64/142 reads (45%) | called by mutect2, pindel
- PKHD1L1 | c.3740C>A p.P1247Q | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PNLIPRP1 | c.1-1G>C p.X1_splice | Splice Site (SNP) | VAF 36/110 reads (33%) | called by muse, mutect2, varscan2
- PPP2R3B | c.1155dup p.D386Rfs*65 | Frame Shift Ins (INS) | VAF 83/290 reads (29%) | called by mutect2, pindel, varscan2
- PRCC | c.75G>C p.E25D | Missense Mutation (SNP) | VAF 212/663 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRDM15 | c.3442A>T p.T1148S | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PSIP1 | c.1417A>G p.T473A | Missense Mutation (SNP) | VAF 151/202 reads (75%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- R3HDM1 | c.2617G>A p.D873N | Missense Mutation (SNP) | VAF 56/140 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.439); called by muse, mutect2
- RNF40 | c.1899G>C p.R633S | Missense Mutation (SNP) | VAF 51/232 reads (22%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- RPS6KA3 | c.2064C>A p.Y688* | Nonsense Mutation (SNP) | VAF 200/601 reads (33%) | called by muse, mutect2, varscan2
- SAGE1 | c.1753_1762del p.E585Kfs*29 | Frame Shift Del (DEL) | VAF 88/141 reads (62%) | called by mutect2, pindel, varscan2
- SLC17A4 | c.1406T>C p.V469A | Missense Mutation (SNP) | VAF 84/265 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- SMARCC1 | c.2646+1G>A p.X882_splice | Splice Site (SNP) | VAF 45/86 reads (52%) | called by muse, mutect2, varscan2
- SMTNL1 | c.719A>G p.E240G (on ENST00000399154; = p.E277G on NM_001105565.2) | Missense Mutation (SNP) | VAF 47/158 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SPIRE2 | c.1781C>T p.A594V | Missense Mutation (SNP) | VAF 148/428 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- STK24 | c.462_463del p.H154Qfs*4 | Frame Shift Del (DEL) | VAF 70/154 reads (45%) | called by pindel, varscan2
- STX3 | c.772_773del p.Q259Gfs*35 | Frame Shift Del (DEL) | VAF 43/185 reads (23%) | called by pindel, varscan2
- TBX21 | c.1296G>A p.W432* | Nonsense Mutation (SNP) | VAF 143/381 reads (38%) | called by muse, mutect2, varscan2
- TDRD15 | c.805A>T p.N269Y | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- TERF2 | c.56del p.D19Afs*140 | Frame Shift Del (DEL) | VAF 77/247 reads (31%) | called by mutect2, pindel, varscan2
- TEX14 | c.3427_3458+15del p.X1143_splice (on ENST00000240361 / NM_001201457.2; = p.X1097_splice on NM_031272.5) | Splice Site (DEL) | VAF 14/74 reads (19%) | called by mutect2, pindel
- TMEM38B | c.4G>C p.D2H | Missense Mutation (SNP) | VAF 103/420 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- TMPRSS7 | c.1672C>T p.P558S (on ENST00000452346; = p.P432S on NM_001042575.2) | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- TOP1 | c.475_477del p.K159del | In Frame Del (DEL) | VAF 14/55 reads (25%) | called by pindel, varscan2
- TRIM9 | c.1073T>G p.V358G | Missense Mutation (SNP) | VAF 120/198 reads (61%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP21 | c.1021G>T p.G341W | Missense Mutation (SNP) | VAF 73/199 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- VAT1L | c.789_790del p.L265Sfs*43 | Frame Shift Del (DEL) | VAF 68/272 reads (25%) | called by mutect2, pindel, varscan2
- YEATS2 | c.2867C>A p.A956D | Missense Mutation (SNP) | VAF 41/172 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- ZFP82 | c.760T>G p.Y254D | Missense Mutation (SNP) | VAF 127/316 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZIM3 | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 68/244 reads (28%) | called by muse, mutect2
- ZNF483 | c.2134del p.I712Ffs*61 | Frame Shift Del (DEL) | VAF 56/345 reads (16%) | called by mutect2, pindel, varscan2
- ZNF517 | c.272C>G p.T91R | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ACACB | c.3522C>T p.H1174= | Silent (SNP) | VAF 53/108 reads (49%) | catalogued as rs1032042057, COSV58143745; called by muse, mutect2, varscan2
- ACSM2B | c.1662C>A p.V554= | Silent (SNP) | VAF 40/219 reads (18%) | called by muse, mutect2, varscan2
- CARD10 | c.873G>T p.T291= | Silent (SNP) | VAF 74/356 reads (21%) | called by muse, mutect2
- CORO7 | c.237A>G p.L79= | Silent (SNP) | VAF 24/179 reads (13%) | called by muse, mutect2, varscan2
- CYSRT1 | c.414C>G p.A138= (on ENST00000409414; = p.A98= on NM_199001.5) | Silent (SNP) | VAF 164/291 reads (56%) | called by muse, mutect2, varscan2
- DNAH17 | c.9747C>G p.V3249= | Silent (SNP) | VAF 118/871 reads (14%) | called by muse, mutect2, varscan2
- EFHC2 | c.477C>T p.V159= | Silent (SNP) | VAF 57/172 reads (33%) | called by muse, mutect2, varscan2
- FAT1 | c.3846C>A p.G1282= | Silent (SNP) | VAF 127/249 reads (51%) | called by muse, mutect2, varscan2
- GRIN3B | c.621G>C p.R207= | Silent (SNP) | VAF 67/122 reads (55%) | called by muse, mutect2, varscan2
- IQSEC2 | c.1779G>C p.L593= (on ENST00000642864 / NM_001111125.3; = p.L388= on NM_015075.2) | Silent (SNP) | VAF 143/410 reads (35%) | called by muse, mutect2, varscan2
- KSR2 | c.1683G>T p.L561= | Silent (SNP) | VAF 38/74 reads (51%) | called by muse, mutect2, varscan2
- MAP6 | c.831G>A p.R277= | Silent (SNP) | VAF 52/410 reads (13%) | called by muse, mutect2, varscan2
- METTL18 | c.465T>G p.S155= | Silent (SNP) | VAF 66/305 reads (22%) | called by muse, mutect2, varscan2
- PCDH8 | c.291C>T p.G97= | Silent (SNP) | VAF 156/433 reads (36%) | catalogued as COSV100131369; called by muse, mutect2, varscan2
- RIN1 | c.2148G>A p.E716= | Silent (SNP) | VAF 85/232 reads (37%) | called by muse, mutect2, varscan2
- SCRN1 | c.27T>C p.C9= | Silent (SNP) | VAF 155/285 reads (54%) | called by muse, mutect2, varscan2
- SLC9A4 | c.1014C>T p.Y338= | Silent (SNP) | VAF 88/289 reads (30%) | catalogued as rs765936170; called by muse, mutect2, varscan2
- TMEM64 | c.288C>G p.G96= | Silent (SNP) | VAF 46/315 reads (15%) | catalogued as COSV69127712; called by muse, mutect2, varscan2
- USP35 | c.537C>G p.A179= | Silent (SNP) | VAF 145/305 reads (48%) | called by muse, mutect2, varscan2
- WDFY4 | c.4272C>G p.L1424= | Silent (SNP) | VAF 85/119 reads (71%) | called by muse, mutect2, varscan2
- ZBP1 | c.453C>T p.H151= | Silent (SNP) | VAF 124/313 reads (40%) | called by muse, mutect2, varscan2
- ZMYM1 | c.210A>G p.S70= | Silent (SNP) | VAF 33/55 reads (60%) | called by muse, varscan2
- AC008758.3 | n.486_487del | RNA (DEL) | VAF 64/212 reads (30%) | called by pindel, varscan2
- AC106795.1 | n.964+50T>C | Intron (SNP) | VAF 19/56 reads (34%) | called by mutect2, varscan2
- ANKRD30A | c.2156-3577G>A | Intron (SNP) | VAF 19/143 reads (13%) | catalogued as rs1276733733; called by mutect2, varscan2
- APOBEC3F | c.172-733C>A | Intron (SNP) | VAF 12/126 reads (10%) | catalogued as rs765140295; called by muse, mutect2, varscan2
- CAPN1 | chr11:65214129 G>C | 3'Flank (SNP) | VAF 147/418 reads (35%) | called by muse, mutect2, varscan2
- CCNB1IP1 | c.-23dup | 5'UTR (INS) | VAF 29/86 reads (34%) | called by mutect2, pindel, varscan2
- CCT3 | c.304+355G>A | Intron (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2, varscan2
- CEP83 | c.1420-22A>C | Intron (SNP) | VAF 25/132 reads (19%) | called by muse, mutect2, varscan2
- DECR2 | c.-47C>G | 5'UTR (SNP) | VAF 46/180 reads (26%) | catalogued as rs906429270; called by muse, mutect2, varscan2
- DRD2 | c.-11C>G | 5'UTR (SNP) | VAF 113/338 reads (33%) | called by muse, mutect2, varscan2
- FAM117B | c.-4del | 5'UTR (DEL) | VAF 8/22 reads (36%) | catalogued as rs927921762; called by mutect2, varscan2
- GZMK | c.-45_-30del | 5'UTR (DEL) | VAF 30/103 reads (29%) | called by mutect2, pindel, varscan2
- LITAF | c.*585dup | 3'UTR (INS) | VAF 20/132 reads (15%) | catalogued as rs953556069; called by mutect2, pindel, varscan2
- MRPL10 | c.52+38G>A | Intron (SNP) | VAF 103/292 reads (35%) | catalogued as rs1462377202; called by muse, mutect2, varscan2
- NCOA3 | c.-16C>G | 5'UTR (SNP) | VAF 14/70 reads (20%) | called by muse, mutect2, varscan2
- RIN2 | c.112-25C>G | Intron (SNP) | VAF 112/281 reads (40%) | called by muse, mutect2, varscan2
- RTN1 | c.1766-23029C>A | Intron (SNP) | VAF 98/172 reads (57%) | catalogued as rs373783767; called by muse, mutect2, varscan2
- SHISA8 | chr22:41909796 C>A | 3'Flank (SNP) | VAF 35/84 reads (42%) | called by muse, mutect2, varscan2
- SREBF1 | c.92-3088A>T | Intron (SNP) | VAF 58/323 reads (18%) | called by muse, mutect2, varscan2
- TBC1D29P | n.2468C>T | RNA (SNP) | VAF 251/372 reads (67%) | called by muse, mutect2, varscan2
- ZNF207 | c.-132G>C | 5'UTR (SNP) | VAF 29/34 reads (85%) | called by muse, mutect2, varscan2
